Surgical pathology report (de-identified scan), TCGA case TCGA-3G-AB0T, project TCGA-THYM (Thymoma), tissue source site MD Anderson Cancer Center, specimen TCGA-3G-AB0T-01A (Primary Tumor).

[page 1 of 4]
Accession: XXXXXXXXXX
Specimen Date/Time:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

- (A) PLEURAL IMPLANT:
THYMOMA IN CONNECTIVE TISSUE (4.0 CM).
- (B) DIAPHRAGMATIC-PLEURAL IMPLANTS:
THYMOMA IN CONNECTIVE TISSUE (LARGEST NODULE 7.0 CM).
- (C) LEFT LOWER LOBE WEDGE RESECTION:
Lung parenchyma, no tumor present.
- (D) AORTIC PLEURA:
Fibroconnective tissue with focal lymphoid follicle, no tumor present.
- (E) RIGHT DIAPHRAGMATIC PLEURA:
Fibroconnective tissue with focal lymphoid follicle, no tumor present.
- (F) ESOPHAGEAL PLEURA:
Fibroconnective tissue with focal lymphoid follicle, no tumor present.
- (G) COSTO-PHRENIC ANGLE:
THYMOMA IN CONNECTIVE TISSUE (0.8 CM).
- (H) CARDIAC PLEURA:
THYMOMA IN CONNECTIVE TISSUE (LARGEST NODULE 0.6 CM).
- (I) ADDITIONAL CARDIAC PLEURA:
THYMOMA IN CONNECTIVE TISSUE (LARGEST NODULE 2.7 CM).
- (J) 6TH RIB:
For gross examination only.

Entire report and diagnosis completed by

GROSS DESCRIPTION

- (A) PLEURAL IMPLANT - A tan-red membranous tissue fragment (8.0 x 3.0 x 1.5 cm). In the midportion of the specimen there is a tan firm nodular mass (4.0 x 1.7 x 1.5 cm).
INK CODE: Blue - edges of specimen
SECTION CODE: Representative sections submitted from tumor to peripheral specimen edge, A1-A7.
- (B) DIAPHRAGMATIC/PLEURAL IMPLANTS - A tan-red membranous tissue fragment (24.0 x 13.0 x 2.7 cm). The specimen contains multiple nodules ranging from 0.3 to 7.0 cm in greatest dimension. Cut sections of these nodules reveal a tan, firm partially necrotic surface.
Representative sections submitted in B1-B7.
- (C) LEFT LOWER LOBE WEDGE RESECTION - A dark red wedge lung resection (4.0 x 3.0 x 0.6 cm) containing a 4.0 cm long staple line. Cut sections reveal unremarkable pulmonary parenchyma.
INK CODE: Blue - adjacent to stapled parenchymal margin.
SECTION CODE: C1, parenchymal margin en face; C2-C4, entirely submitted specimen.
- (D) AORTIC PLEURA - A tan irregular membranous tissue fragment (5.5 x 4.0 x 0.2 cm). Cut section is unremarkable.
SECTION CODE: Entire specimen submitted in D1-D6.
- (E) RIGHT DIAPHRAGMATIC PLEURA - A tan-red membranous tissue fragment (2.5 x 2.3 x 0.3 cm). Cut section reveals a fibrous surface.
SECTION CODE: E1, entire specimen submitted in E1-E3.
- (F) ESOPHAGEAL PLEURA - A tan irregular membranous tissue fragment (3.0 x 1.7 x 0.3 cm). Cut section is unremarkable.
SECTION CODE: Entire specimen submitted in F1 and F2.

COF ICD-O-3
Thymoma, type B1, malignant
path 8580/3
Thymoma NOS malignant
8580/3
Site: Thymus C379
path Mediastinum NOS C38.3
90615/14

[page 2 of 4]
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

(G) COSTO-PHRENIC ANGLE - A tan irregular membranous tissue fragment (2.5 x 1.7 x 0.2 cm). A tan nodular firm mass (0.8 x 0.6 x 0.3 cm) is noted.

SECTION CODE: Entire specimen submitted in G1-G2.

(H) CARDIAC PLEURA - Multiple tan irregular tissue fragments (5.0 x 4.0 x 0.2 cm in aggregate). Cut section reveals multiple nodules ranging from 0.3 to 0.6 cm in greatest dimension.

Representative sections submitted in H1 and H2.

(I) ADDITIONAL CARDIAC PLEURA - Multiple tan irregular membranous tissue fragment (5.5 x 4.5 x 0.3 cm). The specimen contains multiple nodules ranging from 1.0 to 2.7 cm in greatest dimension.

SECTION CODE: Representative sections submitted in I1 and I2.

(J) 6TH RIB - Four tan-red rib segments (ranging from 1.0 x 1.0 x 0.9 cm to 5.5 x 1.6 x 0.5 cm). The specimen is submitted to the bone lab for further processing.

CLINICAL HISTORY

Mass, left lung.

SNOMED CODES

T-29000, M-80506

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

Start of ADDENDUM

*Per TSS dx discrepancy form,
TC6A tumor is thymoma, B1.*

1/29/14

QUANTIFIED / *DISQUANTIFIED*

[page 3 of 4]
Page: 3

[REDACTED] M
Accession: [REDACTED]
Specimen Date/Time: [REDACTED]

ADDENDUM

Addendum completed by

DIAGNOSIS

(J) 6TH RIB:

Bone tissue submitted for decalcification is free of tumor.

Released by:

-----END OF REPORT-----

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on _____) Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Thymoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	B1	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Histologic subtype was not done at initial pathologic diagnosis. Reviewing Pathologist has re-reviewed the case slide and provided the WHO subtype	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my Institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my Institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 00aa7c7f-dede-4cbd-9e74-30a103dce68f (TCGA-3G-AB0T.C865D85C-7DC0-4740-8AC5-38490B0A1C31.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).